Surgical pathology report (de-identified scan), TCGA case TCGA-YT-A95F, project TCGA-THYM (Thymoma), tissue source site Barretos Cancer Hospital, specimen TCGA-YT-A95F-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Mediastinum

Description: "Excision of mediastinal tumor":

The morphological aspects associated to the immunohistochemistry profile (see complementary exam) are compatible with the diagnosis of Type AB Thymoma (WHO).

Surgical margins uninvolved by neoplasia.

ICD O. 3
Thymoma, type AB NOS
8582/1
Site Anterior mediastinum -
path C38.1
Mediastinum NOS C38.3
JAS 3/13/14

Criteria	WJ 11/17/13	Yes	No
For Malignancy History			✓

Source: NCI Genomic Data Commons file f1ebf87f-caf0-4833-9ad0-a9d26353887c (TCGA-YT-A95F.BF066BA9-0185-4691-8DC9-A354E0331DC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).